Gene-level copy-number profile of tumor specimen TCGA-2A-AAYF-01A from TCGA case TCGA-2A-AAYF, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.1 years (20,866 days).
Specimen TCGA-2A-AAYF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.b49720d9-9fe2-4811-8a88-24e5ca4d696f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2A-AAYF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/134e8694-a966-4540-859c-34c9ca3cbb77

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 3,521; copy number 2: 56,282; copy number 3: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2A-AAYF-01A-11D-A41J-01): tumor purity 0.84, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:32,763,438–33,676,796, 15 genes: RNY1P4, AL138820.1, LINC00423, TOMM22P3, KL, STARD13, STARD13-IT1, STARD13-AS, AL627232.1, LINC02344, AL138999.2, AL138999.1, AL139383.1, AL161719.1, AL139081.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,134. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
